Somatic mutation profile of tumor specimen TCGA-HT-7482-01A (aliquot TCGA-HT-7482-01A-11D-2024-08) from TCGA case TCGA-HT-7482, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 18.8 years (6,857 days).
Specimen TCGA-HT-7482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 817c4003-c0b0-4834-95c1-73e18c7cd1f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7482-10A (Blood Derived Normal), aliquot TCGA-HT-7482-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a26e42a-03c5-4994-a846-43837f9b51b0

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 1, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 19/69 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.444T>A p.D148E | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV71152315; called by muse, mutect2, varscan2
- ATRX | c.6055A>G p.K2019E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64878656; called by muse, mutect2, varscan2
- BRSK2 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs767016763, COSV57544949; called by muse, mutect2, varscan2
- DPPA4 | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as COSV59511373; called by muse, mutect2
- JCAD | c.2493G>C p.L831F | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV64760480; called by muse, mutect2, varscan2
- KHDRBS2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1237289698, COSV55468078, COSV99832645; called by muse, mutect2, varscan2
- MET | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV59260253; called by muse, mutect2, varscan2
- MUC5AC | c.1555C>G p.P519A | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); catalogued as COSV62254495; called by muse, mutect2
- PLXNA1 | c.2355C>G p.N785K | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1008154383, COSV52528745; called by muse, mutect2, varscan2
- RBM41 | c.1242G>T p.*414Yext*13 | Nonstop Mutation (SNP) | VAF 44/212 reads (21%) | catalogued as COSV52564178; called by muse, mutect2, varscan2
- SLC2A12 | c.164G>C p.G55A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51600444, COSV51600939; called by muse, mutect2, varscan2
- PRDM14 | c.336G>A p.P112= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs746412127, COSV52570706; called by muse, mutect2
- SLC6A15 | c.2121T>C p.A707= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as COSV57025725; called by muse, mutect2
- SRL | c.1215C>T p.F405= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs377743040; called by muse, mutect2, varscan2
- VPS41 | c.1614C>T p.D538= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs146405914; called by muse, mutect2, varscan2
- PDZD2 | c.8219-176G>A | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99223313; called by muse, mutect2, varscan2
